Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-7044, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-7044-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Other Related Data:

Billing Type:

Financial Number:

Clinical Diagnosis & History:

Left renal mass.

Specimens Submitted:

1: SP: Left kidney and adrenal

DIAGNOSIS:

- 1) KIDNEY AND ADRENAL GLAND, LEFT NEPHRECTOMY AND ADRENALECTOMY:
- RENAL CELL CARCINOMA, PAPILLARY TYPE, WITH FOCAL SPINDLE CELL (SARCOMATOID) GROWTH AND EXTENSIVE NECROSIS. THE TUMOR GREATEST DIAMETER IS 10.0 CM. THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA. NO INVASION OF THE RENAL VEIN IS IDENTIFIED. ALL SURGICAL MARGINS ARE FREE OF TUMOR. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE. THE ADRENAL GLAND IS UNREMARKABLE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1) The specimen is received fresh labelled "Left kidney and adrenal". It consists of a kidney with attached adrenal gland, almost entirely covered by adipose tissue, which totally weighs 720 grams. The kidney measures 14 cm in superior-inferior, 10 cm anterior - posterior, and 9.5 cm medial to lateral. The adrenal gland measures 4.5 x 2 x 0.7 cm, and on cut section is unremarkable. The surgical margins of the vein and of the ureter are shaved off. The kidney is bisected to reveal an almost entirely necrotic mass, which is located in the cortical portion of the specimen. The mass measures 10 x 6 x 5 cm, and is centrally, diffusely occupied by brown necrotic tissue. In the

[page 2 of 2]
peripheral portion, the mass consists of soft, yellow to dark red tissue. The mass appears encapsulated and well demarcated except in the most superior portion where it appears to infiltrate the surrounding adipose tissue. The external surface consists of fibrous tissue and it is unclear if residual kidney parenchyma surrounds the tumor. The pelvic fat appears not involved by the tumor. The uninvolved kidney appears unremarkable. Representative sections are submitted.

Summary of Sections:

AG - adrenal gland

DM - adrenal vascular margin

V - vein

T - tumor

OK - unremarkable kidney

Histo Stain Results/Comments:

Stain/Procedure Name	Result	Comment
----------------------	--------	---------

REVIEW ADDITIONAL H&E

Summary of Sections:

Part	Part	Size	Blocks	Pieces	Aliq
1	add	2	3		N
	AG	1	1		
	T	6		M	
	OK	1		1	
	DM	2		M	
	V	1		2	

Source: NCI Genomic Data Commons file 026be35a-4528-4a87-9d09-29a50116d942 (TCGA-BQ-7044.DF325D36-7617-4333-B4E4-3D18F5F651DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).